Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7099, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7099-01A (Primary Tumor).

[page 1 of 4]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT BUCCAL MARGIN:
Squamous mucosa with moderate dysplasia. Margins are free of tumor.
- (B) RIGHT PALATE AND MARGIN:
Squamous mucosa, no tumor present.
- (C) DEEP BUCCAL MARGIN:
Fibroadipose tissue. No tumor present.
- (D) MUCOSA OF MAXILLARY SINUS:
Respiratory mucosa, no tumor present.
- (E) SUPERIOR MARGIN (TRUE MARGIN INKED):
Fibromyxoid mucosa. No tumor present.
- (F) LEFT INFERIOR TURBINATE:
Fibrovascular tissue. No tumor present.
- (G) POSTERIOR MARGIN:
Squamous mucosa. No tumor present.
- (H) SOFT PALATE, TRUE MARGIN:
Squamous mucosa with acute and chronic inflammation, no tumor present.
- (I) DEEP MARGIN, LEFT RETROMOLAR TRIGONE:
Fibroconnective tissue. No tumor present.
- (J) LEFT MANDIBULAR MARGIN:
Fibroconnective tissue. No tumor present.
- (K) RIGHT INFERIOR TURBINATE:
Fibrovascular tissue. No tumor present.
- (L) MAXILLARY SINUS MUCOSA:
Respiratory mucosa. No tumor present.
- (M) LEFT MAXILLA TOTAL PALATECTOMY IN A BLOCK INCISION THAT INCLUDES PART OF THE LEFT MAXILLA, HARD PALATE AND SOFT PALATE:
INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED WITH A DEPTH OF INVASION OF 0.5 CM.

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

- (A) LEFT BUCCAL MARGIN, TWO MARGINS INKED, STITCH IS EQUAL TO SUPERIOR – The specimen is covered on one aspect by skin and on the other by mucosa. The superior end is marked by a stitch. The true margin is inked yellow. The true margin is submitted in sections one to four starting from superior to inferior. The remaining specimen is submitted in section five.

[page 2 of 4]
[REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(B) RIGHT PALATE AND MARGIN – Three portions of unremarkable tan-pink mucosa (0.4 x 0.1 x 0.1 cm, 1.1 x 0.1 x 0.1 cm, and 0.9 x 0.5 x 0.2 cm). The true margin of each portion of tissue has been inked previously by the surgeon.

INK CODE: Yellow-true margin.

SECTION CODE: B1, two smaller portions of mucosa submitted for frozen section; B2, B3, perpendicular margin largest portion of mucosa submitted entirely for frozen section. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(C) DEEP BUCCAL MARGIN – A portion of adipose tissue (3.5 x 1.5 x 0.5 cm). The true margin is inked purple by the surgeon. The cut surface shows unremarkable adipose tissue.

INK CODE: Blue-true deep margin.

SECTION CODE: C1-C7, entirely submitted specimen (perpendicular margins) for frozen section. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(D) MUCOSA OF MAXILLARY SINUS – A white-pink irregular fragment of tissue (1.0 x 0.7 x 0.2 cm). The specimen is dissected and entirely submitted in D. [REDACTED]

(E) SUPERIOR MARGIN, TRUE MARGIN INKED – Received an elongated, thin ellipse of skin (2.1 x 0.1 cm) excised to a depth of 0.2 cm. The true margin is inked with blue ink. The specimen is serially sectioned and entirely submitted for frozen section.

INK CODE: True margin-yellow.

SECTION CODE: E1, entire specimen. [REDACTED]

*FS/DX NO TUMOR PRESENT. [REDACTED]

(F) LEFT INFERIOR TURBINATE - Multiple light pink irregular soft tissue, in aggregate 1.9 x 2.1 x 0.5 cm. Entirely submitted.

SECTION CODE: F, specimen in toto. [REDACTED]

(G) POSTERIOR MARGIN – A portion of tan-pink soft tissue (2.2 x 0.5 x 0.5 cm). The true margin is inked on surface previously by the surgeon.

INK CODE: Blue-true margin.

SECTION CODE: G1-G3, perpendicular sections of true margin submitted entirely for frozen section. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(H) SOFT PALATE, TRUE MARGIN – A tan-pink portion of soft tissue (3.0 x 2.1 x 0.8 cm). The surface has been previously inked by the surgeon designating the true margin.

A trapezoid piece of mucosal soft tissue (3.0 x 2.5 x 0.4 cm). The true resection margin is marked with blue ink. Cut surfaces are unremarkable.

INK CODE: Blue-true margin.

H1, H2, bisected tissue with the margin submitted en face. H3-H5, specimen with perpendicular margin. [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(I) DEEP MARGIN, LEFT RETROMOLAR TRIGONE – Two portions of tan-pink tissue (1.5 x 1.0 x 0.9 cm and 1.0 x 0.5 x 0.3 cm). The true margin has been inked previously by the surgeon.

INK CODE: Blue-true margin.

SECTION CODE: I1, smaller portion of tissue, perpendicular margin; I2-I4, larger portion of tissue, perpendicular margin (submitted entirely). [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(J) LEFT MANDIBULAR MARGIN – A tan-pink portion of soft tissue (0.9 x 0.5 x 0.2 cm). One surface of the specimen has been previously inked by the surgeon and designated the true margin. Submitted entirely for frozen section.

INK CODE: Blue, true margin [REDACTED]

*FS/DX: NO TUMOR PRESENT. [REDACTED]

(K) RIGHT INFERIOR TURBINATE – A 3.0 x 1.3 x 0.6 cm polyp mucosal soft tissue with a diffusely congested out surface. Representative sections are submitted in [REDACTED]

[page 3 of 4]
[REDACTED]

(L) MAXILLARY SINUS MUCSOA – A 4.0 x 2.0 x 0.1 cm transparent mucosa with attached fragments of bone. No abnormalities are identified. The entire soft tissue submitted in L1 and the bony part is for submitted in L2 for decalcification. [REDACTED]

(M) LEFT MAXILLA TOTAL PALATECTOMY IN A BLOCK INCISION THAT INCLUDES PART OF THE LEFT MAXILLA, HARD PALATE AND SOFT PALATE, which is 5.5 cm anterior to posterior, 4.3 cm lateral to lateral, and 2.8 cm superior to inferior. The attached soft tissue extends 4.0 cm beyond these one margins. The soft palate mucosa has a 2.0 cm ulcer with irregular edges and necrotic base. This corresponds to a tumor which invades the underlying soft tissue to a maximum depth of 1.0 cm. The adjacent mucosa overlying the hard palate is finely granular and has a verrucous architecture. It seems to be confined to the mucosa and submucosa. The soft tissue is sequentially submitted for grossing from the medial to the lateral aspect of the specimen. The bony parts are sent to the bone lab for decalcification.

INK CODE: Black-posterior and medial, one resection margin

SECTION CODE: M1-M2, the entire soft tissue including the tumor and adjacent lesion, progressing from he medial to the later; M22, he posterior bony resection margin [REDACTED]

CLINICAL HISTORY

Squamous cell carcinoma, retromolar trigone and palate.

SNOMED CODES

[page 4 of 4]
ADDENDUM

DIAGNOSIS

- (L) MAXILLARY SINUS MUCOSA:
MINUTE FRAGMENT OF SQUAMOUS CARCINOMA. MARGINS FREE.
- (M) LEFT MAXILLA, TOTAL PALATECTOMY:
SQUAMOUS CARCINOMA INVADING PERIOSTEUM AND SUPERFICIAL BONE.
Bony margins of resection free of tumor.

Entire report and diagnosis completed by

Released by:

Source: NCI Genomic Data Commons file ca671db2-285c-4eb1-9eb4-618299afcc12 (TCGA-CV-7099.FC628E16-6A65-4B69-94AA-FC494111F0CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).